Gene-level copy-number profile of tumor specimen TCGA-85-A511-01A from TCGA case TCGA-85-A511, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.3 years (22,759 days).
Specimen TCGA-85-A511-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d936adeb-c2b6-42bc-8e1f-4634cf49f1d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-A511-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f571fed4-bd9a-425d-98d0-eae40ec7bded

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,101; copy number 2: 24,897; copy number 3: 22,903; copy number 4: 7,230; copy number 5: 990; copy number 6: 573; copy number 7: 328; copy number 8: 600; copy number 9: 1,075; copy number 10: 66; copy number 11: 28; copy number 15: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-A511-01A-21D-A25M-01): tumor purity 0.25, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,649 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:12,702,764–17,386,417, 49 genes, copy number 6–15: AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1, AC093912.1, AC073062.1, LINC00276, AC016730.1, RNU6-1288P, Metazoa_SRP, AC011897.1, LRATD1, AC068286.2, AC068286.1, NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10.
- chr3:77,811,741–81,105,182, 20 genes, copy number 6: RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027.
- chr3:104,063,039–107,421,338, 29 genes, copy number 5 (within-gene range 3–5): RAP1BP2, AC091804.1, ALCAM, CBLB, AC131237.1, AC079382.1, AC079382.2, LINC00882, Y_RNA, AC080097.1, Y_RNA, FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14, RNU6-1308P, AC117435.1, AC074043.1, DUBR, AC063944.1, CSP2, AC063944.2.
- chr3:127,689,062–198,222,513, 1,259 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–8 (broad region; genes not listed).
- chr7:98,877,933–101,321,823, 145 genes, copy number 5 (broad region; genes not listed).
- chr7:101,388,868–101,389,080, 1 gene, copy number 5: AC004965.1.
- chr8:35,235,475–35,796,550, 1 gene, copy number 11 (within-gene range 2–11): UNC5D.
- chr8:35,525,176–36,191,194, 5 genes, copy number 11 (within-gene range 4–11): LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3.
- chr9:30,558,880–43,045,120, 390 genes, copy number 5–8 (broad region; genes not listed).
- chr11:29,980,113–31,817,961, 19 genes, copy number 5: LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1, PAX6.
- chr11:68,612,899–73,761,137, 171 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 214. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
